TCGA case TCGA-EM-A3AN — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: University Health Network. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6491d025-c061-4180-bfd4-d7c6e6e55f66

Demographics
Sex at birth: female; Country of residence at enrollment: Canada; Age at index: 36 years; Vital status: Alive.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 36.1 years (13,188 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T1b; AJCC pathologic N: N1b; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 1,006 days (2.8 years); Tumor focality: Multifocal.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 27; Lymph nodes tested: 80; Measurement unit: Centimeters; Tumor depth measurement: 1; Tumor length measurement: 1.2; Tumor width measurement: 1.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 142 days; Days to treatment end: 142 days; Treatment dose: 125 mCi; Treatment outcome: Complete Response; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Prescribed dose: 125; Prescribed dose units: mCi; Pretreatment: Thyroxine Withdrawal; Timepoint category: First Treatment.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Treatment dose: 125 mCi; Pretreatment: rhTSH.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Prescribed dose: 125; Prescribed dose units: mCi; Pretreatment: rhTSH; Timepoint category: First Treatment.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Treatment dose: 125 mCi; Pretreatment: Thyroxine Withdrawal.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation, External Beam.

Follow-up (4 entries)
- Days to follow up: 341 days; Disease response: Tumor Free.
- Days to follow up: 1,006 days (2.8 years); Disease response: Tumor Free.
- Imaging type: CT Scan; Imaging anatomic site: Lymph Node; Timepoint: Preoperative.
- Follow-up contact recording only the day: day 597.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Nodular Hyperplasia.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EM-A3AN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 120 mg.
  Slide TCGA-EM-A3AN-01A-01-TSA: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-EM-A3AN-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EM-A3AN-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Classical/usual; Laterality: Right lobe; Lymph nodes preop imaging: Yes; Lymph nodes examined: Yes; Genotypic analysis detected: No.
- Patient personal medical history thyroid gland disorder names: History thyroid disease: Nodular Hyperplasia.
- Neoplasm dimension: Tumor size width: 1.0.
- Lymph node preoperative assessment diagnostic imaging types: Lymph nodes preop imaging type: CT with contrast.
- Follow-up form 1: Lost to follow-up: No; I 131 radiation first treatment dose: 125 mci; I 131 radiation treatment cumulative dose: 125 mci; Radiation therapy xrt method prep: Patient Did Not Receive External Radiation Therapy; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; I 131 radiation first treatment method: rhTSH; I 131 radiation first treatment dose: 125 mCi; I 131 radiation treatment cumulative dose: 125 mCi; Radiation therapy xrt method prep: Patient Did Not Receive External Radiation Therapy; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,006 days; disease-specific survival: no event (censored), 1,006 days; progression-free interval: no event (censored), 1,006 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EM-A3AN-01A-11D-A201-01): tumor purity 0.64, ploidy 2, whole-genome doublings 0.
